Somatic mutation profile of tumor specimen MP2PRT-PASYIR-TMP1-A (aliquot MP2PRT-PASYIR-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASYIR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,458 days).
Specimen MP2PRT-PASYIR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60893ecc-b78b-44d5-a0f9-f7c1cab8a7eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYIR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYIR-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e122e055-6a3d-4907-90bb-d0b69c007d4b

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 161/444 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.431); catalogued as rs1057517719, COSV65424948; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 131/401 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1345037350, COSV57420026; called by muse, mutect2, varscan2
- CREBBP | c.3914+1G>A p.X1305_splice | Splice Site (SNP) | VAF 14/350 reads (4%) | catalogued as COSV52131286; called by muse, mutect2
- CREBBP | c.3103G>T p.E1035* | Nonsense Mutation (SNP) | VAF 94/286 reads (33%) | catalogued as COSV99273434; called by muse, mutect2, varscan2
- FAT3 | c.10043C>T p.A3348V | Missense Mutation (SNP) | VAF 29/410 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs376234071, COSV53112247; called by muse, mutect2
- LZTR1 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 23/658 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1372731834; called by muse, mutect2
- OR5I1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.349); catalogued as rs777329573, COSV100041191, COSV56885436; called by muse, mutect2, varscan2
- ATRX | c.6311_6316delinsTGGCC p.D2104Vfs*5 | Frame Shift Del (DEL) | VAF 69/95 reads (73%) | called by pindel, varscan2*
- IGHV2-26 | chr14:106301392 GTGGTATCC>CCCAGG | Missense Mutation (DEL) | VAF 112/337 reads (33%) | called by pindel, varscan2*
- CLU | c.1020A>G p.K340= | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- PCDHA11 | c.1839G>C p.A613= | Silent (SNP) | VAF 205/512 reads (40%) | catalogued as COSV100254200; called by muse, mutect2, varscan2
- RARA | c.1113C>T p.P371= | Silent (SNP) | VAF 20/572 reads (3%) | catalogued as rs1305217007; called by muse, mutect2
- PI4KB | c.-29+1094G>A | Intron (SNP) | VAF 162/399 reads (41%) | catalogued as rs868447897, COSV99649390; called by muse, mutect2, varscan2
